TCGA case TCGA-23-1117 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a88b7e66-5f12-4023-a7e2-fcfbd1f25977

Demographics
Sex at birth: female; Race: white; Age at index: 42 years; Vital status: Dead; Days to death: 1,013 days (2.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 43.0 years (15,690 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 294 days; Number of cycles: 11; Treatment dose: 6,470 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 459 days (1.3 years); Days to treatment end: 624 days (1.7 years); Number of cycles: 8; Treatment dose: 92 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 712 days (1.9 years); Days to treatment end: 757 days (2.1 years); Number of cycles: 3; Treatment dose: 3,450 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 781 days (2.1 years); Days to treatment end: 863 days (2.4 years); Number of cycles: 5; Treatment dose: 600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 890 days (2.4 years); Days to treatment end: 928 days (2.5 years); Number of cycles: 5; Treatment dose: 280 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trastuzumab; Initial disease status: Progressive Disease; Days to treatment start: 890 days (2.4 years); Days to treatment end: 928 days (2.5 years); Number of cycles: 5; Treatment dose: 600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 951 days (2.6 years); Days to treatment end: 993 days (2.7 years); Number of cycles: 4; Treatment dose: 3,960 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 44.1 years (16,108 days); Days to diagnosis: 418 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 438 days (1.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 418 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 418 days (1.1 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 1,013 days (2.8 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Biopsy with Histologic Confirmation; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-1117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-23-1117-01A-01-BS1: Section location: Top; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5.
  Slide TCGA-23-1117-01A-02-BS2: Section location: Bottom; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5.
- Sample TCGA-23-1117-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-1117-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 7: Pharmaceutical therapy drug name: Herceptin; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-23-1117-01A-02D-0428-01): tumor purity 0.69, ploidy 3.31, whole-genome doublings 1.
